Somatic mutation profile of tumor specimen TCGA-06-1087-01A (aliquot TCGA-06-1087-01A-02W-0611-08) from TCGA case TCGA-06-1087, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.7 years (27,658 days).
Specimen TCGA-06-1087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e8b88d5-9b0b-4904-8c1b-1fa269d495b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-1087-10A (Blood Derived Normal), aliquot TCGA-06-1087-10A-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ecedf92-8532-410c-b656-f92a90551c14

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 1, Splice Site 1, Translation Start Site 1, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 128/303 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV99558755; called by muse, mutect2
- ACVR2A | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as COSV99603999; called by muse, mutect2, varscan2
- BCAR3 | c.1673G>C p.S558T | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV99550333; called by muse, mutect2, varscan2
- BHMT | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 43/564 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV57154280, COSV99165375; called by muse, mutect2
- CACNA1E | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 202/381 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100701362, COSV100701897; called by muse, mutect2, varscan2
- CCDC87 | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100039778; called by muse, mutect2, varscan2
- CCR9 | c.322G>A p.A108T (on ENST00000357632 / NM_031200.3; = p.A96T on NM_006641.4) | Missense Mutation (SNP) | VAF 27/511 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100591603; called by muse, mutect2
- CILK1 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 44/832 reads (5%) | catalogued as COSV100607553; called by muse, mutect2
- CNKSR3 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 21/741 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV101401299; called by muse, mutect2
- COL6A3 | c.7263G>A p.M2421I | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV99796406; called by muse, mutect2, varscan2
- COLQ | c.4G>T p.V2F | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as COSV101082829; called by muse, mutect2
- CSMD2 | c.4015C>A p.L1339M | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99586724; called by muse, mutect2
- DCAF13 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs768741309, COSV99885060; called by muse, mutect2, varscan2
- DOCK4 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101447794; called by muse, mutect2, varscan2
- DSG4 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 139/225 reads (62%) | catalogued as rs147705128, COSV57389297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 895/1633 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1421390269, COSV61459230; called by muse, mutect2, varscan2
- FGD6 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100676401; called by mutect2, varscan2
- FGGY | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 27/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100363909; called by muse, mutect2
- FSCN3 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs750865630, COSV99756859; called by muse, varscan2
- HARS2 | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217958, COSV99217991; called by muse, mutect2, varscan2
- IL1R2 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1212654339, COSV100207759; called by muse, mutect2
- KCNH5 | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV100525535; called by muse, mutect2, varscan2
- KLHL13 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99451112; called by muse, mutect2, varscan2
- KRT36 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as rs375968431; called by muse, mutect2, varscan2
- NUMA1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | catalogued as COSV100705848; called by muse, mutect2
- OR1L8 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs372497222; called by muse, mutect2, varscan2
- PADI3 | c.408G>A p.K136= | Splice Region (SNP) | VAF 27/40 reads (68%) | catalogued as rs926001906, COSV100968407; called by muse, mutect2, varscan2
- POGZ | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 117/299 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99652401; called by muse, mutect2, varscan2
- PTK7 | c.2566G>T p.A856S | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV100029901, COSV57849023; called by muse, varscan2
- RB1 | c.2306T>A p.L769* | Nonsense Mutation (SNP) | VAF 49/62 reads (79%) | catalogued as CM030515, COSV57308877, COSV99923448; called by muse, mutect2, varscan2
- RDH5 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99141716; called by muse, mutect2, varscan2
- RND3 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 18/276 reads (7%) | catalogued as COSV99811897; called by muse, mutect2
- SAGE1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 57/58 reads (98%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as COSV61013152; called by muse, mutect2, varscan2
- SEM1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 74/1318 reads (6%) | catalogued as COSV101303885; called by muse, mutect2
- SLAMF7 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV100833209, COSV63564029; called by muse, mutect2
- SLC9A3R1 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV99379860; called by muse, mutect2
- STK32B | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 331/378 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777255527, COSV51484845; called by muse, mutect2, varscan2
- STX19 | c.236T>A p.V79E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100115188; called by muse, mutect2, varscan2
- TECTA | c.1949G>A p.C650Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99878841; called by muse, mutect2
- TMPRSS11B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/197 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.281); catalogued as COSV100219253, COSV60294784; called by muse, mutect2
- TP63 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 178/704 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1455505991, COSV53213979; called by muse, mutect2, varscan2
- TRIM24 | c.1018A>G p.M340V | Missense Mutation (SNP) | VAF 424/993 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100630714; called by muse, mutect2, varscan2
- UGT2A1 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 115/146 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV54147324; called by muse, mutect2, varscan2
- ZNF354C | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100203496; called by muse, mutect2
- ARID3B | c.715del p.I239Sfs*18 | Frame Shift Del (DEL) | VAF 10/130 reads (8%) | called by mutect2, varscan2
- MGA | c.2985_2990del p.M996_D997del | In Frame Del (DEL) | VAF 144/538 reads (27%) | called by mutect2, pindel, varscan2
- SGO1 | c.1265del p.P422Qfs*20 | Frame Shift Del (DEL) | VAF 54/123 reads (44%) | called by mutect2, pindel, varscan2
- TAS2R10 | c.908del p.N303Ifs*? | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- APOB | c.10254G>A p.T3418= | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as rs781639766, COSV51928882; called by muse, mutect2, varscan2
- CKM | c.1023G>T p.R341= | Silent (SNP) | VAF 36/488 reads (7%) | catalogued as COSV99487929; called by muse, mutect2
- CREB3L4 | c.477C>A p.P159= | Silent (SNP) | VAF 13/260 reads (5%) | catalogued as COSV99665616; called by muse, mutect2
- GABRA2 | c.219C>T p.Y73= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs201391789, COSV62920252; called by muse, mutect2
- HSPB3 | c.228C>T p.D76= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs761293721, COSV57356774, COSV57357254; called by muse, mutect2, varscan2
- KCNK5 | c.1251C>T p.D417= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs138652901; called by muse, mutect2, varscan2
- MAGI1 | c.1593A>G p.T531= | Silent (SNP) | VAF 108/423 reads (26%) | catalogued as rs139017628; called by muse, mutect2, varscan2
- NCOA7 | c.2232C>G p.T744= | Silent (SNP) | VAF 22/244 reads (9%) | catalogued as COSV99996580; called by muse, mutect2
- ODAM | c.309C>T p.A103= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as rs1482866397, COSV101258035, COSV68573126; called by muse, mutect2, varscan2
- PLXNA2 | c.1272G>A p.L424= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100885196; called by muse, mutect2, varscan2
- PTGER3 | c.1161T>C p.H387= | Silent (SNP) | VAF 268/628 reads (43%) | catalogued as COSV100138372; called by muse, varscan2
- SMC5 | c.1635T>C p.Y545= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs772601817, COSV100746980; called by muse, varscan2
- ZNF410 | c.792G>A p.Q264= | Silent (SNP) | VAF 34/416 reads (8%) | catalogued as COSV100206274; called by muse, mutect2
- MIR522 | n.29C>T | RNA (SNP) | VAF 16/75 reads (21%) | catalogued as rs765188254; called by muse, mutect2, varscan2
- SLC25A3 | c.645-76A>T | Intron (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99499004; called by muse, mutect2, varscan2
